Somatic mutation profile of tumor specimen TCGA-DD-AAW0-01A (aliquot TCGA-DD-AAW0-01A-11D-A40R-10) from TCGA case TCGA-DD-AAW0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.7 years (19,981 days).
Specimen TCGA-DD-AAW0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95d79de9-0911-40b1-a9db-ea3a6bc67088.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAW0-10A (Blood Derived Normal), aliquot TCGA-DD-AAW0-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/869dd699-74c9-43e6-9a5e-62b69ea75101

The open-access MAF lists 105 somatic variants for this specimen: 82 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 22, Splice Site 5, Nonsense Mutation 3, Frame Shift Del 3, Intron 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs371511486; called by muse, mutect2, varscan2
- AFTPH | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99480581; called by muse, mutect2, varscan2
- ASXL2 | c.2899A>G p.I967V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99710899; called by muse, mutect2, varscan2
- ATF6B | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV100913558, COSV64322408; called by muse, mutect2, varscan2
- BANK1 | c.1111G>C p.A371P | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100536203; called by muse, mutect2, varscan2
- CACNA2D1 | c.2002A>C p.N668H (on ENST00000356253 / NM_001366867.1; = p.N656H on NM_000722.4) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV100666492; called by muse, mutect2, varscan2
- CAPN6 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100136837; called by muse, mutect2, varscan2
- CDON | c.3848A>T p.Q1283L (on ENST00000392693 / NM_001243597.2; = p.Q1260L on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV99701161; called by muse, mutect2, varscan2
- CLGN | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 134/427 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57775265; called by muse, mutect2, varscan2
- CLGN | c.251T>C p.M84T | Missense Mutation (SNP) | VAF 109/397 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100346562; called by muse, mutect2, varscan2
- CRYBG1 | c.2258T>G p.V753G | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.044); catalogued as rs776196166, COSV100954453; called by muse, mutect2, varscan2
- CTNNA2 | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV100783433; called by muse, mutect2, varscan2
- CYP2B6 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100137493; called by muse, mutect2, varscan2
- DCAF4L2 | c.533G>T p.C178F | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV100150787; called by muse, mutect2
- DENND4A | c.5125A>G p.M1709V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV101475312; called by muse, mutect2, varscan2
- DIO2 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101375859, COSV70446485; called by muse, mutect2, varscan2
- DLGAP4 | c.2401C>T p.R801C (on ENST00000339266 / NM_001365621.1; = p.R798C on NM_014902.6) | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs763337013, COSV100211114; called by muse, mutect2, varscan2
- DOCK8 | c.1044G>C p.K348N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101210210; called by muse, mutect2, varscan2
- ELAPOR2 | c.1089+1G>C p.X363_splice (on ENST00000450689 / NM_001142749.3; = p.X196_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99788643; called by muse, mutect2, varscan2
- EMP1 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as COSV99916918; called by muse, mutect2, varscan2
- EPSTI1 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100552832; called by muse, mutect2, varscan2
- ERBB3 | c.3448G>C p.G1150R | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99916622, COSV99918114; called by muse, mutect2, varscan2
- ERC2 | c.2224G>C p.D742H | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99883611; called by muse, mutect2, varscan2
- FBN2 | c.4081G>A p.G1361R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99326854; called by muse, mutect2, varscan2
- FBXO44 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99278858; called by muse, mutect2, varscan2
- FCRL2 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.119); catalogued as rs144215277, COSV100829811; called by muse, mutect2, varscan2
- GALNT14 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368328840, COSV61106479, COSV61108274; called by muse, mutect2, varscan2
- GTF2E1 | c.1207T>C p.F403L | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.08); catalogued as COSV99381890; called by muse, mutect2, varscan2
- HERC2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV99872899, COSV99873672; called by muse, mutect2, varscan2
- HMMR | c.963A>T p.L321F | Missense Mutation (SNP) | VAF 153/878 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV100700988; called by muse, mutect2, varscan2
- KDM2A | c.2005T>A p.C669S | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as COSV100445524; called by muse, mutect2, varscan2
- KHDRBS3 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV100878487, COSV100878535; called by muse, mutect2, varscan2
- KLHL28 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100753084; called by muse, mutect2, varscan2
- LRP1 | c.9110A>G p.Y3037C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99675540; called by muse, mutect2, varscan2
- MCCC2 | c.1649A>G p.N550S | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as rs745984390, COSV100040099; called by muse, mutect2, varscan2
- MIB1 | c.1748T>G p.L583W | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99838667; called by muse, mutect2, varscan2
- MTREX | c.2488A>G p.I830V | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs754413662, COSV100043903; called by muse, mutect2, varscan2
- MYCBP2 | c.11611-1G>C p.X3871_splice (on ENST00000357337; = p.X3909_splice on NM_015057.5) | Splice Site (SNP) | VAF 11/67 reads (16%) | catalogued as COSV62037258; called by muse, mutect2, varscan2
- MYH10 | c.2078A>T p.H693L | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.55); catalogued as rs1372136199, COSV99344943; called by muse, mutect2, varscan2
- MYO18A | c.2315A>G p.N772S | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100572172; called by muse, mutect2, varscan2
- MYO6 | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100889342; called by muse, mutect2, varscan2
- MYT1L | c.3020C>A p.T1007K | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101217070, COSV67702885; called by muse, mutect2, varscan2
- NFKB2 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV99502991; called by muse, mutect2, varscan2
- NKX6-1 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55683931; called by muse, mutect2
- OAS1 | c.1109C>A p.T370K | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.026); catalogued as COSV99177118; called by muse, mutect2, varscan2
- OBI1 | c.1635G>A p.M545I | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1029305297, COSV99932423; called by muse, mutect2, varscan2
- OR5H14 | c.257T>C p.L86S | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV101454152; called by muse, mutect2, varscan2
- PAXX | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV100860381; called by muse, mutect2, varscan2
- PFDN5 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54475184, COSV99229210; called by muse, mutect2, varscan2
- PRRT3 | c.1980G>A p.W660* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99926468; called by muse, mutect2, varscan2
- PSMA5 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99600503; called by muse, mutect2, varscan2
- PSTPIP1 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV99143650; called by muse, mutect2, varscan2
- RUNX2 | c.1361A>G p.Y454C (on ENST00000371438; = p.Y432C on NM_001015051.3) | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216479084, COSV100767305; called by muse, mutect2, varscan2
- RUVBL2 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV99668962; called by muse, varscan2
- SDK1 | c.5107A>G p.M1703V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1387415100, COSV101269234; called by muse, mutect2, varscan2
- SELENOT | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1281748032, COSV101517709; called by muse, mutect2
- SHCBP1L | c.549G>T p.L183F | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1401456935, COSV100840974; called by muse, mutect2, varscan2
- SHQ1 | c.1459A>G p.T487A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV100344848; called by muse, mutect2, varscan2
- SLC15A4 | c.187A>T p.N63Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99903532; called by muse, mutect2
- SLC38A9 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769081599, COSV100591358; called by muse, mutect2, varscan2
- SLC5A7 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs1484945457, COSV50896605; called by muse, mutect2
- SLC5A8 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs200408412, COSV101610541; called by muse, mutect2, varscan2
- SLIT3 | c.2131T>A p.C711S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60623046; called by muse, mutect2, varscan2
- SMPD2 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs768794675, COSV99237936; called by muse, mutect2, varscan2
- SPEF2 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99214026; called by muse, mutect2, varscan2
- SRRM2 | c.5059C>T p.R1687* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as rs1299610405, COSV100070643; called by muse, mutect2, varscan2
- STS | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99481185; called by muse, mutect2, varscan2
- SUSD2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100844277, COSV64204104; called by mutect2, varscan2
- TRPC3 | c.1866C>G p.S622R (on ENST00000379645 / NM_001366479.2; = p.S549R on NM_003305.2) | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312502; called by muse, mutect2, varscan2
- TSR3 | c.768-1G>A p.X256_splice | Splice Site (SNP) | VAF 18/133 reads (14%) | catalogued as COSV99136186; called by muse, mutect2, varscan2
- TTN | c.68710C>A p.L22904I (on ENST00000591111; = p.L15480I on NM_003319.4) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | PolyPhen benign (0); catalogued as COSV100607682; called by muse, mutect2, varscan2
- TUBD1 | c.255A>C p.Q85H | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV100360053; called by muse, mutect2, varscan2
- ZEB2 | c.3387T>A p.S1129R | Missense Mutation (SNP) | VAF 103/448 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV100355778, COSV57958613; called by muse, mutect2, varscan2
- ZNF709 | c.1778G>A p.C593Y | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101172159; called by muse, varscan2
- AHNAK2 | c.7291_7293dup p.K2431dup | In Frame Ins (INS) | VAF 32/172 reads (19%) | called by pindel, varscan2
- ALB | c.1731_1740del p.F578Sfs*27 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- CEMIP | c.2761_2763del p.N921del | In Frame Del (DEL) | VAF 14/54 reads (26%) | called by pindel, varscan2
- EPHB4 | c.1870+2del p.X624_splice | Splice Site (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- FETUB | c.424+2dup p.X142_splice | Splice Site (INS) | VAF 44/222 reads (20%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.3415G>T p.A1139S | Missense Mutation (SNP) | VAF 87/979 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2
- SLC25A52 | c.707del p.G236Dfs*10 (on ENST00000672005; = p.G226Dfs*10 on NM_001034172.4) | Frame Shift Del (DEL) | VAF 96/435 reads (22%) | called by mutect2, pindel, varscan2
- TNPO1 | c.1882_1883del p.L628Cfs*14 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | called by pindel, varscan2
- ACSL5 | c.699A>T p.L233= (on ENST00000354273; = p.L289= on NM_016234.3) | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV100634559; called by muse, mutect2, varscan2
- ANKRD13B | c.1335G>A p.S445= | Silent (SNP) | VAF 58/220 reads (26%) | catalogued as rs1340694245, COSV100801207; called by muse, mutect2, varscan2
- CNOT6L | c.387T>C p.T129= (on ENST00000504123 / NM_001286790.2; = p.T124= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 154/509 reads (30%) | catalogued as COSV99361698; called by muse, mutect2, varscan2
- CPZ | c.702C>T p.H234= (on ENST00000360986 / NM_001014447.3; = p.H223= on NM_003652.3) | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as rs753008564, COSV100248920; called by muse, mutect2, varscan2
- DDX5 | c.1347C>T p.N449= | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as COSV99857858; called by muse, mutect2, varscan2
- EMB | c.579C>T p.Y193= | Silent (SNP) | VAF 44/764 reads (6%) | catalogued as COSV100296787; called by muse, mutect2
- FANCF | c.780G>A p.L260= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV100541807; called by muse, mutect2, varscan2
- HECW1 | c.672C>T p.N224= | Silent (SNP) | VAF 21/275 reads (8%) | catalogued as COSV101223327; called by muse, mutect2
- INTS2 | c.1857C>A p.V619= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV52157937, COSV99248028; called by muse, mutect2
- KRT12 | c.1383T>C p.S461= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV99288917; called by muse, mutect2, varscan2
- LRRC7 | c.2250A>T p.T750= (on ENST00000651989 / NM_001370785.2; = p.T717= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV99226170; called by muse, mutect2, varscan2
- MAP3K7CL | c.42G>A p.E14= | Silent (SNP) | VAF 56/206 reads (27%) | catalogued as rs1347414727, COSV99726516; called by muse, mutect2, varscan2
- MEGF9 | c.384G>A p.P128= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100879368; called by muse, mutect2, varscan2
- OPLAH | c.534G>A p.G178= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as COSV101470758; called by muse, mutect2, varscan2
- PPP4R2 | c.27G>T p.A9= | Silent (SNP) | VAF 67/253 reads (26%) | catalogued as COSV99865945; called by muse, mutect2, varscan2
- RGS17 | c.540T>G p.T180= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as COSV52806168, COSV99242795; called by muse, mutect2
- SALL3 | c.1836C>A p.P612= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV101609982, COSV101610007; called by muse, mutect2, varscan2
- SYCP2L | c.888G>T p.P296= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs761928920, COSV51651058, COSV99305048; called by muse, mutect2, varscan2
- UBC | c.429G>T p.L143= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV100298925; called by muse, mutect2, varscan2
- VILL | c.1428C>T p.S476= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs769280415, COSV52184779; called by muse, mutect2, varscan2
- WAC | c.1119G>A p.T373= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as rs377502318; called by muse, mutect2, varscan2
- ZNF211 | c.675A>G p.G225= (on ENST00000347302 / NM_198855.4; = p.G238= on NM_006385.5) | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as COSV99560214; called by muse, mutect2, varscan2
- RBM44 | c.-98-2942A>G | Intron (SNP) | VAF 71/289 reads (25%) | catalogued as COSV100389784; called by muse, mutect2, varscan2
